Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A7SS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A7SS-01A (Primary Tumor).

[page 1 of 3]
Result Date:

Performed By:

Encounter

ICD O-3
Carcinoma, papillary renal cell
Site @ Kidney 103
8260/3
@64.9
9/10/4/13

Surgical Pathology Report***Final***

Surgical Pathology Report

Name:

DIAGNOSIS:

- A. Precaval lymph node: One lymph node, negative for malignancy (0/1).
- B. Right renal mass, partial nephrectomy: Papillary renal cell carcinoma, type 2, 2.9 cm in greatest dimension (see synoptic report below).
- Procedure/laterality: Partial nephrectomy, right.
- Histologic type: Papillary renal cell carcinoma, type 2.
- Nuclear grade (Fuhrman, 1-4): 3.
- Tumor size: 2.9 cm.
- Tumor site: Right posterior midpole.
- Tumor focality: Unifocal.
- Sarcomatoid features: Not identified.
- Tumor necrosis: Not identified.
- Microscopic tumor extension:
- Extension into perinephric tissue: Not identified.
- Extension beyond Gerota's fascia: Not identified
- Extension into renal sinus: Not identified.
- Extension into renal vein: Not identified.
- Extension into collecting system: Not identified.
- Surgical margins: Renal parenchymal margin negative by at least 0.3 cm.
- Lymph-vascular invasion: Not identified.
- Pathologic findings in nonneoplastic kidney: No additional findings.
- Pathologic staging: pT1a.
- C. Additional precaval lymph node: One lymph node, negative for malignancy (0/1).

CLINICAL INFORMATION:

Right renal mass.

SPECIMEN(S):

[page 2 of 3]
A:Precaval lymph node
B:Right renal mass
C:Additional precaval lymph node

: A1 B1 B2 B3 B4 C1

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:
Intraoperative Pathologist(s):

A. Precaval lymph nodes, frozen section diagnosis: Negative for malignancy.

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled and "precaval lymph node" is a 2 cm fatty lymph node entirely submitted for frozen section in one cassette labeled

B. Received fresh labeled and "right renal mass".

Procedure: Partial nephrectomy.

Specimen laterality: Right.

Tumor site: Right posterior mid pole.

Tumor size: 2.9 x 2.5 x 2.0 cm.

Tumor focality: Unifocal.

Gross extent of tumor:

Extension into perinephric tissue: Absent.

Extension beyond Gerota's fascia: Absent.

Extension into renal sinus: Absent.

Extension into renal vein: Absent.

Extension into collecting system: Absent.

Adrenal gland: Absent.

Gross Notes:

Gross tumor characteristics: The tumor is 2.9 cm in maximum dimension and has a bright yellow-red color with focal necrosis. The tumor is at least 0.4 cm from the nearest inked parenchymal margin. The tumor is adherent to the pericapsular fat which is inked blue.

Block summary for specimen

1) tumor with margin.

2-3) sections of tumor.

4) tumor with capsule.

Fresh normal tissue and fresh tumor are submitted for

C. Received fresh labeled and "additional precaval lymph node" is a piece of adipose tissue, 5 cm in maximum dimension. Within the adipose tissue is one fatty lymph node, 3.8 cm in maximum dimension. The entire lymph node is bisected and submitted in one cassette labeled

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not

[page 3 of 3]
necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ('CLIA') as qualified to perform high complexity clinical laboratory testing.

IIHAA Discrepancy		✓

Source: NCI Genomic Data Commons file 3c59993c-6b6f-4fd6-8b60-6abeba058d16 (TCGA-SX-A7SS.2176416F-1584-454C-92C6-CA520C40E902.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).